Somatic mutation profile of tumor specimen C3L-03962-03 (aliquot CPT0233120006) from CPTAC case C3L-03962, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 65.7 years (23,986 days).
Specimen C3L-03962-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7a727add-af02-468a-9b07-d44b78aa03cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03962-31 (Blood Derived Normal), aliquot CPT0233260002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0a1c489c-97cd-4dd3-9bbe-8e538084b801

The open-access MAF lists 325 somatic variants for this specimen: 201 protein-altering or splice-affecting, 68 silent, 56 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 156, Silent 68, Intron 34, Frame Shift Del 14, Nonsense Mutation 13, RNA 11, In Frame Del 7, 3'UTR 5, Splice Region 4, Splice Site 3, 5'Flank 3, 5'UTR 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CREBBP | c.5039_5041del p.S1680del | In Frame Del (DEL) | VAF 246/630 reads (39%) | hotspot (GDC flag); catalogued as rs587783502; called by pindel, varscan2
- PIK3CA | c.3127A>G p.M1043V | Missense Mutation (SNP) | VAF 8/132 reads (6%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.026); catalogued as rs1057519936, COSV55879858, COSV55890961; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 307/568 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC11 | c.2770G>T p.A924S | Missense Mutation (SNP) | VAF 186/366 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.035); catalogued as rs138453043; called by muse, mutect2, varscan2
- AC131160.1 | c.642C>G p.F214L | Missense Mutation (SNP) | VAF 85/582 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as rs1356923946; called by muse, mutect2, varscan2
- AGMO | c.512G>A p.W171* | Nonsense Mutation (SNP) | VAF 30/108 reads (28%) | catalogued as COSV61116260; called by muse, mutect2, varscan2
- ALYREF | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 85/164 reads (52%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.836); catalogued as rs1401978105; called by muse, mutect2, varscan2
- AMPD2 | c.1974_1976del p.L659del | In Frame Del (DEL) | VAF 15/84 reads (18%) | catalogued as rs771742899; called by mutect2, pindel, varscan2
- ATP10A | c.1302G>C p.E434D | Missense Mutation (SNP) | VAF 53/225 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63521375; called by muse, mutect2, varscan2
- BHLHA9 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 57/103 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs917142739; called by muse, mutect2, varscan2
- CCDC178 | c.824C>G p.S275C | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as COSV55769162, COSV55793829; called by muse, mutect2, varscan2
- CDC42BPB | c.597-5_597-2del p.X199_splice | Splice Site (DEL) | VAF 21/93 reads (23%) | catalogued as rs768769729; called by mutect2, pindel, varscan2
- CEP85L | c.1681G>C p.D561H | Missense Mutation (SNP) | VAF 59/215 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV63829726; called by muse, mutect2, varscan2
- CES5A | c.1059G>A p.K353= | Splice Region (SNP) | VAF 24/300 reads (8%) | catalogued as COSV51868530; called by muse, mutect2
- CLEC6A | c.203G>T p.S68I | Missense Mutation (SNP) | VAF 72/193 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.656); catalogued as COSV65987324; called by muse, varscan2
- CLVS2 | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.342); catalogued as rs771884601, COSV99252842; called by muse, mutect2, varscan2
- CNTN5 | c.152G>T p.R51I | Missense Mutation (SNP) | VAF 77/639 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV54298321; called by muse, mutect2, varscan2
- COL22A1 | c.91G>T p.G31C | Missense Mutation (SNP) | VAF 107/323 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1340568724; called by muse, mutect2, varscan2
- CRAT | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 76/333 reads (23%) | SIFT tolerated (0.28); PolyPhen benign (0.088); catalogued as rs763023389, COSV58876641; called by muse, mutect2, varscan2
- CSMD3 | c.9803C>A p.P3268H (on ENST00000297405 / NM_001363185.1; = p.P3099H on NM_052900.3) | Missense Mutation (SNP) | VAF 101/327 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV99852422; called by muse, mutect2, varscan2
- CUL2 | c.596C>G p.P199R | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.438); catalogued as COSV101039206; called by muse, mutect2, varscan2
- CYP2C9 | c.332-2A>G p.X111_splice | Splice Site (SNP) | VAF 173/581 reads (30%) | catalogued as rs111553080; called by muse, mutect2, varscan2
- DCAF4L2 | c.1070C>A p.P357H | Missense Mutation (SNP) | VAF 52/252 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs765137281, COSV100150640, COSV100150926; called by muse, mutect2, varscan2
- DDX60L | c.3503del p.N1168Tfs*25 | Frame Shift Del (DEL) | VAF 18/54 reads (33%) | catalogued as rs772416332; called by mutect2, varscan2
- DEF8 | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 31/257 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.243); catalogued as rs376968565; called by muse, mutect2, varscan2
- DLGAP2 | c.706G>T p.V236L | Missense Mutation (SNP) | VAF 172/400 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs753025360, COSV70096595; called by muse, mutect2, varscan2
- DPP10 | c.1757C>G p.S586C | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100058060, COSV59685352; called by muse, mutect2, varscan2
- ERICH6 | c.118G>C p.E40Q | Missense Mutation (SNP) | VAF 50/432 reads (12%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.025); catalogued as COSV55799082; called by muse, varscan2
- FAM135B | c.2926C>G p.P976A | Missense Mutation (SNP) | VAF 56/252 reads (22%) | SIFT tolerated, low confidence (0.82); PolyPhen benign (0.011); catalogued as COSV99417072; called by muse, mutect2, varscan2
- FAM78A | c.14del p.F5Sfs*36 | Frame Shift Del (DEL) | VAF 22/118 reads (19%) | catalogued as rs758104834; called by mutect2, pindel, varscan2
- FAT2 | c.7343C>G p.S2448C | Missense Mutation (SNP) | VAF 82/300 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV55817036; called by muse, mutect2, varscan2
- FSIP2 | c.9577G>C p.D3193H | Missense Mutation (SNP) | VAF 35/180 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV58084325; called by muse, mutect2, varscan2
- GAP43 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 149/289 reads (52%) | SIFT tolerated (0.21); PolyPhen benign (0.169); catalogued as rs773812326; called by muse, mutect2, varscan2
- GLI2 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 92/412 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.462); catalogued as rs1265447957; called by muse, mutect2, varscan2
- GNA15 | c.108G>C p.K36N | Missense Mutation (SNP) | VAF 97/341 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV53585227; called by muse, mutect2, varscan2
- GON4L | c.1888C>G p.L630V | Missense Mutation (SNP) | VAF 111/585 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.712); catalogued as COSV99675260; called by muse, mutect2, varscan2
- H4C12 | c.311G>C p.*104Sext*? | Nonstop Mutation (SNP) | VAF 75/280 reads (27%) | catalogued as COSV62743637, COSV62743749; called by muse, mutect2, varscan2
- JAM3 | c.572G>A p.R191H | Missense Mutation (SNP) | VAF 152/598 reads (25%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as rs367727226; called by muse, mutect2, varscan2
- LAMA1 | c.1499G>C p.C500S | Missense Mutation (SNP) | VAF 141/570 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1469380359, COSV67534381; called by muse, mutect2, varscan2
- LRRTM1 | c.1256C>T p.A419V | Missense Mutation (SNP) | VAF 77/367 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.036); catalogued as rs1310070413, COSV99702204; called by muse, mutect2, varscan2
- MAP3K14 | c.2206_2208del p.E736del | In Frame Del (DEL) | VAF 108/294 reads (37%) | catalogued as rs1330841533; called by pindel, varscan2
- MARK1 | c.2102G>C p.R701P | Missense Mutation (SNP) | VAF 44/204 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65069679; called by muse, varscan2
- METTL15 | c.523A>G p.M175V | Missense Mutation (SNP) | VAF 33/148 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs753752723; called by muse, mutect2, varscan2
- MPP2 | c.667G>A p.A223T (on ENST00000461854 / NM_001278372.2; = p.A199T on NM_005374.5) | Missense Mutation (SNP) | VAF 39/622 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.028); catalogued as rs1255356198, COSV52235929; called by muse, mutect2
- NOTCH3 | c.572G>T p.G191V | Missense Mutation (SNP) | VAF 221/709 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1435747730; called by muse, mutect2, varscan2
- OVGP1 | c.949C>A p.Q317K | Missense Mutation (SNP) | VAF 51/224 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100868254; called by muse, mutect2, varscan2
- OXA1L | c.733G>A p.E245K (on ENST00000285848; = p.E185K on NM_005015.5) | Missense Mutation (SNP) | VAF 76/235 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.911); catalogued as rs747372512; called by muse, mutect2, varscan2
- OXGR1 | c.937G>C p.V313L | Missense Mutation (SNP) | VAF 76/146 reads (52%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs1245931531; called by muse, mutect2, varscan2
- PCDHA11 | c.434C>G p.S145C | Missense Mutation (SNP) | VAF 109/414 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); catalogued as rs551651050, COSV56502178; called by muse, mutect2, varscan2
- PCSK4 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 115/398 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142181980; called by muse, mutect2, varscan2
- PCSK7 | c.1675C>T p.P559S | Missense Mutation (SNP) | VAF 48/285 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as rs764759455; called by muse, mutect2, varscan2
- PDSS2 | c.101C>A p.S34* | Nonsense Mutation (SNP) | VAF 98/296 reads (33%) | catalogued as COSV100941622; called by muse, mutect2, varscan2
- PEAK1 | c.423G>C p.K141N | Missense Mutation (SNP) | VAF 69/258 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as COSV56930520; called by muse, mutect2, varscan2
- PPP1R12C | c.758C>T p.P253L | Missense Mutation (SNP) | VAF 56/172 reads (33%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.691); catalogued as rs1338150136; called by muse, mutect2, varscan2
- PRLR | c.1241C>A p.S414* | Nonsense Mutation (SNP) | VAF 84/895 reads (9%) | catalogued as COSV51495438; called by muse, mutect2
- PTPRT | c.3073G>T p.V1025F | Missense Mutation (SNP) | VAF 88/281 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61967363; called by muse, mutect2, varscan2
- PTPRT | c.2161C>A p.R721S | Missense Mutation (SNP) | VAF 16/163 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.561); catalogued as COSV61967335, COSV62035210; called by muse, mutect2
- RBM5 | c.2179G>A p.D727N | Missense Mutation (SNP) | VAF 91/461 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.017); catalogued as rs1295310135; called by muse, mutect2, varscan2
- RIMS2 | c.1812+2T>C p.X604_splice (on ENST00000666250 / NM_001348490.2; = p.X412_splice on NM_014677.5 and 7 other RefSeq transcripts) | Splice Site (SNP) | VAF 20/90 reads (22%) | catalogued as COSV51685780; called by muse, mutect2, varscan2
- RNASEL | c.628C>G p.L210V | Missense Mutation (SNP) | VAF 16/422 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.108); catalogued as COSV62376830; called by muse, mutect2
- SAMSN1 | c.862A>G p.N288D | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs930904425; called by muse, mutect2, varscan2
- SPTA1 | c.6038T>C p.L2013P | Missense Mutation (SNP) | VAF 258/629 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs759083985; called by muse, mutect2, varscan2
- STYXL1 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 264/813 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.204); catalogued as rs1163715541, COSV50389175; called by muse, mutect2, varscan2
- SYNE2 | c.4511C>T p.T1504I | Missense Mutation (SNP) | VAF 86/338 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs748016794; called by muse, mutect2, varscan2
- TBC1D8 | c.1606G>T p.V536L | Missense Mutation (SNP) | VAF 58/222 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.717); catalogued as rs779489061, COSV65212004; called by muse, mutect2, varscan2
- TGM4 | c.667G>C p.E223Q | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV56097059; called by muse, mutect2, varscan2
- TMEM132C | c.750C>G p.N250K | Missense Mutation (SNP) | VAF 30/162 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.691); catalogued as COSV70659367; called by muse, mutect2, varscan2
- TRPA1 | c.1206C>G p.I402M | Missense Mutation (SNP) | VAF 105/413 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs989658771; called by muse, mutect2, varscan2
- UBA1 | c.1243G>A p.G415R | Missense Mutation (SNP) | VAF 29/249 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs373305404, COSV60113746; ClinVar: benign; called by muse, mutect2, varscan2
- UBL3 | c.55G>C p.G19R | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV66209421; called by muse, mutect2, varscan2
- WDR36 | c.545G>A p.G182D | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV72411118; called by muse, mutect2, varscan2
- WNK4 | c.3560G>A p.R1187H | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757221134, COSV55907318; called by muse, mutect2, varscan2
- ZAN | c.5122G>A p.A1708T | Missense Mutation (SNP) | VAF 18/216 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.59); catalogued as rs371235933; called by muse, mutect2
- ZNF676 | c.1559C>A p.T520K (on ENST00000650058; = p.T488K on NM_001001411.3) | Missense Mutation (SNP) | VAF 55/292 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.041); catalogued as rs372702194; called by muse, mutect2, varscan2
- ZNF880 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 75/302 reads (25%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); catalogued as rs1485543627; called by muse, mutect2, varscan2
- ZNF93 | c.1112G>A p.C371Y | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759122167; called by muse, mutect2, varscan2
- ADAMTS12 | c.4582C>T p.Q1528* | Nonsense Mutation (SNP) | VAF 90/178 reads (51%) | called by muse, mutect2, varscan2
- ADGRE3 | c.1281C>A p.H427Q | Missense Mutation (SNP) | VAF 83/278 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- AKAP9 | c.6793A>G p.T2265A (on ENST00000359028; = p.T2241A on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- AL136295.1 | c.1951G>A p.D651N | Missense Mutation (SNP) | VAF 51/195 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- ANKRD53 | c.245C>T p.S82L | Missense Mutation (SNP) | VAF 87/388 reads (22%) | SIFT tolerated (0.64); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- APOL1 | c.1165_1167del p.Y389del | In Frame Del (DEL) | VAF 16/63 reads (25%) | called by mutect2, pindel, varscan2
- ASTN2 | c.3704G>T p.R1235L (on ENST00000313400 / NM_001365069.1; = p.R1184L on NM_014010.5) | Missense Mutation (SNP) | VAF 134/277 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ATF1 | c.122C>A p.S41Y | Missense Mutation (SNP) | VAF 74/396 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- B3GALNT1 | c.649G>A p.G217R | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.847); called by muse, varscan2
- BCHE | c.630A>G p.I210M | Missense Mutation (SNP) | VAF 77/193 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BRINP3 | c.2153A>T p.Q718L | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- C2CD5 | c.681T>G p.D227E | Missense Mutation (SNP) | VAF 200/475 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CACNG3 | c.853G>T p.D285Y | Missense Mutation (SNP) | VAF 207/478 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- CCDC7 | c.775G>T p.D259Y | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.539); called by muse, mutect2, varscan2
- CCL5 | c.270G>A p.M90I | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CD2AP | c.16G>T p.V6L | Missense Mutation (SNP) | VAF 75/202 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CDC42BPG | c.1518G>C p.Q506H | Missense Mutation (SNP) | VAF 63/241 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- CDK13 | c.1322G>T p.S441I | Missense Mutation (SNP) | VAF 72/259 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CDX4 | c.328T>G p.S110A | Missense Mutation (SNP) | VAF 127/242 reads (52%) | SIFT tolerated (0.4); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- CHD1 | c.3226T>A p.C1076S | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- CIP2A | c.368T>A p.L123H | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CNTNAP4 | c.1398T>G p.S466R | Missense Mutation (SNP) | VAF 161/272 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- COL11A1 | c.4375G>T p.G1459C | Missense Mutation (SNP) | VAF 50/226 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPEB3 | c.567G>C p.Q189H | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by mutect2, varscan2
- CSMD3 | c.820G>C p.E274Q | Missense Mutation (SNP) | VAF 39/312 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- DAB2 | c.537G>C p.K179N | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.018); called by muse, mutect2
- DAPL1 | c.215A>G p.Y72C | Missense Mutation (SNP) | VAF 74/263 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- DMBT1 | c.251C>T p.S84L | Missense Mutation (SNP) | VAF 58/292 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DZIP3 | c.3530G>C p.W1177S | Missense Mutation (SNP) | VAF 25/165 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EEF1G | c.683del p.K228Rfs*110 | Frame Shift Del (DEL) | VAF 114/499 reads (23%) | called by mutect2, pindel, varscan2
- ELMO1 | c.1358A>T p.E453V | Missense Mutation (SNP) | VAF 57/205 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- EPB41L2 | c.1897-5G>C | Splice Region (SNP) | VAF 46/220 reads (21%) | called by muse, mutect2, varscan2
- EPB41L3 | c.591dup p.E198* | Frame Shift Ins (INS) | VAF 22/129 reads (17%) | called by mutect2, pindel, varscan2
- ERICH3 | c.4517C>A p.T1506N | Missense Mutation (SNP) | VAF 66/227 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- FASTKD3 | c.583A>T p.S195C | Missense Mutation (SNP) | VAF 51/278 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- FMN2 | c.2587del p.C863Afs*24 | Frame Shift Del (DEL) | VAF 61/315 reads (19%) | called by mutect2, pindel, varscan2
- FOLH1 | c.664G>T p.A222S | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- FRG2C | c.800T>A p.I267K | Missense Mutation (SNP) | VAF 72/972 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.965); called by muse, mutect2
- FUT7 | c.445A>G p.I149V | Missense Mutation (SNP) | VAF 288/527 reads (55%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- FXYD6 | c.214C>A p.P72T | Missense Mutation (SNP) | VAF 107/437 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- FYCO1 | c.345G>T p.Q115H | Missense Mutation (SNP) | VAF 124/387 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- GALNT14 | c.617G>T p.R206M | Missense Mutation (SNP) | VAF 37/337 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.516); called by muse, varscan2
- GRK4 | c.130G>C p.E44Q | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- HP1BP3 | c.1145A>G p.H382R | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- IFITM10 | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 66/163 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IFT80 | c.1376A>T p.H459L | Missense Mutation (SNP) | VAF 26/229 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- IGDCC4 | c.2705A>C p.Q902P | Missense Mutation (SNP) | VAF 148/462 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- IRF3 | c.142_144del p.Q48del | In Frame Del (DEL) | VAF 32/264 reads (12%) | called by pindel, varscan2
- KANSL1L | c.2143G>A p.E715K | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- KCNG2 | c.683G>A p.W228* | Nonsense Mutation (SNP) | VAF 54/208 reads (26%) | called by muse, mutect2, varscan2
- KCNH8 | c.1657del p.E553Nfs*61 | Frame Shift Del (DEL) | VAF 89/320 reads (28%) | called by mutect2, pindel, varscan2
- KCNN3 | c.1749C>A p.I583= (on ENST00000618040 / NM_001204087.1; = p.I568= on NM_002249.6) | Splice Region (SNP) | VAF 86/462 reads (19%) | called by muse, mutect2, varscan2
- KLHL1 | c.627G>T p.Q209H | Missense Mutation (SNP) | VAF 91/200 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- KNOP1 | c.967G>C p.D323H | Missense Mutation (SNP) | VAF 86/466 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- KRT13 | c.314_316del p.K105del | In Frame Del (DEL) | VAF 143/650 reads (22%) | called by pindel, varscan2
- KRTAP1-1 | c.203_204del p.S68* | Frame Shift Del (DEL) | VAF 184/1321 reads (14%) | called by pindel, varscan2
- LAMA1 | c.6410C>A p.T2137N | Missense Mutation (SNP) | VAF 93/336 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- LONRF2 | c.2172G>T p.E724D | Missense Mutation (SNP) | VAF 69/243 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- LRIT1 | c.621C>A p.C207* | Nonsense Mutation (SNP) | VAF 14/63 reads (22%) | called by muse, mutect2, varscan2
- LYAR | c.858G>C p.K286N | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- LYST | c.4017_4018del p.R1339Sfs*45 | Frame Shift Del (DEL) | VAF 22/138 reads (16%) | called by pindel, varscan2
- LYST | c.2105A>T p.E702V | Missense Mutation (SNP) | VAF 57/143 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.25); called by muse, mutect2, varscan2
- MAGEB18 | c.623T>C p.F208S | Missense Mutation (SNP) | VAF 162/207 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MKLN1 | c.813_814del p.G272Rfs*7 | Frame Shift Del (DEL) | VAF 47/188 reads (25%) | called by pindel, varscan2
- MUC17 | c.8608C>A p.L2870I | Missense Mutation (SNP) | VAF 59/221 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- MUC4 | c.5197A>T p.S1733C | Missense Mutation (SNP) | VAF 172/2459 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.709); called by muse, mutect2
- MYO18A | c.4198G>T p.E1400* | Nonsense Mutation (SNP) | VAF 162/377 reads (43%) | called by muse, mutect2, varscan2
- MYO7A | c.5998A>T p.T2000S | Missense Mutation (SNP) | VAF 62/234 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NCOA2 | c.2746C>T p.Q916* | Nonsense Mutation (SNP) | VAF 91/300 reads (30%) | called by muse, mutect2, varscan2
- NKPD1 | c.20T>A p.V7D | Missense Mutation (SNP) | VAF 66/261 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- NLRP11 | c.1412T>A p.I471N | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- OMG | c.229T>G p.Y77D | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- OR1L8 | c.497_504del p.R166Lfs*3 | Frame Shift Del (DEL) | VAF 75/189 reads (40%) | called by mutect2, pindel, varscan2
- OR2T33 | c.292C>A p.Q98K | Missense Mutation (SNP) | VAF 194/1439 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- PAXIP1 | c.2090T>A p.V697E | Missense Mutation (SNP) | VAF 96/331 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- PCDHGA9 | c.2228T>C p.V743A | Missense Mutation (SNP) | VAF 91/362 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PDHA2 | c.655A>C p.I219L | Missense Mutation (SNP) | VAF 64/221 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- PKHD1 | c.8269C>T p.P2757S | Missense Mutation (SNP) | VAF 141/370 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLCB3 | c.3187C>A p.Q1063K | Missense Mutation (SNP) | VAF 73/301 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- POU2F2 | c.145A>G p.T49A | Missense Mutation (SNP) | VAF 30/239 reads (13%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); called by muse, mutect2
- PPEF2 | c.240C>A p.D80E | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRORP | c.639_640del p.Y213* | Frame Shift Del (DEL) | VAF 24/160 reads (15%) | called by mutect2, pindel, varscan2
- PWP1 | c.1050G>C p.W350C | Missense Mutation (SNP) | VAF 49/282 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PWWP2B | c.832G>T p.E278* | Nonsense Mutation (SNP) | VAF 152/356 reads (43%) | called by muse, mutect2, varscan2
- RALGAPA1 | c.4726G>C p.E1576Q | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- RPL8 | c.89G>C p.R30P | Missense Mutation (SNP) | VAF 15/333 reads (5%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.991); called by muse, mutect2
- RUNX1T1 | c.557A>G p.K186R (on ENST00000265814 / NM_001198628.1; = p.K159R on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- SAMSN1 | c.304C>A p.H102N | Missense Mutation (SNP) | VAF 50/182 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- SEC24B | c.2899G>A p.E967K | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2, varscan2
- SELENOI | c.512A>G p.H171R | Missense Mutation (SNP) | VAF 83/276 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- SESN2 | c.77C>G p.S26W | Missense Mutation (SNP) | VAF 54/286 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- SHB | c.342C>A p.Y114* | Nonsense Mutation (SNP) | VAF 146/777 reads (19%) | called by muse, mutect2, varscan2
- SIK2 | c.2720_2721del p.F907* | Frame Shift Del (DEL) | VAF 59/280 reads (21%) | called by mutect2, pindel
- SINHCAF | c.27G>A p.M9I | Missense Mutation (SNP) | VAF 152/390 reads (39%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC22A8 | c.952T>C p.F318L | Missense Mutation (SNP) | VAF 57/323 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- SLC39A12 | c.451A>T p.R151W | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SLITRK3 | c.2867T>A p.L956* | Nonsense Mutation (SNP) | VAF 27/249 reads (11%) | called by muse, mutect2, varscan2
- SPICE1 | c.1486G>T p.E496* | Nonsense Mutation (SNP) | VAF 67/284 reads (24%) | called by muse, mutect2, varscan2
- SRI | c.256_257del p.M86Vfs*8 | Frame Shift Del (DEL) | VAF 53/497 reads (11%) | called by pindel, varscan2
- STARD9 | c.5653G>C p.E1885Q | Missense Mutation (SNP) | VAF 62/270 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- STK11IP | c.2168G>A p.G723E | Missense Mutation (SNP) | VAF 107/301 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SYNE1 | c.20001G>T p.M6667I (on ENST00000367255 / NM_182961.4; = p.M6596I on NM_033071.3) | Missense Mutation (SNP) | VAF 112/455 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TANC1 | c.2486del p.N829Tfs*26 | Frame Shift Del (DEL) | VAF 32/160 reads (20%) | called by mutect2, pindel, varscan2
- TAS2R20 | c.664A>G p.K222E | Missense Mutation (SNP) | VAF 25/213 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- TMEM132C | c.302C>A p.P101H | Missense Mutation (SNP) | VAF 124/284 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TNRC6A | c.3343A>T p.S1115C | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (1); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- TRIML1 | c.752T>A p.L251Q | Missense Mutation (SNP) | VAF 74/220 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- TRPM6 | c.4126G>A p.E1376K | Missense Mutation (SNP) | VAF 85/339 reads (25%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TTN | c.21343G>C p.V7115L (on ENST00000591111; = p.V6188L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/112 reads (46%) | PolyPhen benign (0.075); called by muse, mutect2, varscan2
- UMODL1 | c.3560T>A p.V1187E (on ENST00000408910 / NM_001004416.2; = p.V1315E on NM_173568.3) | Missense Mutation (SNP) | VAF 63/215 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- UNC13B | c.490_491del p.Q164Efs*14 | Frame Shift Del (DEL) | VAF 36/284 reads (13%) | called by mutect2, pindel, varscan2
- UNC5D | c.1418C>T p.S473L | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- UNC80 | c.8531G>A p.R2844Q | Missense Mutation (SNP) | VAF 124/625 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- UNC93A | c.449T>A p.V150E | Missense Mutation (SNP) | VAF 109/460 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- USP33 | c.2671+7_2671+8del | Splice Region (DEL) | VAF 14/75 reads (19%) | called by mutect2, pindel, varscan2
- WDFY3 | c.6698dup p.A2234Sfs*8 | Frame Shift Ins (INS) | VAF 79/266 reads (30%) | called by mutect2, pindel, varscan2
- ZFAT | c.2221G>A p.D741N | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.291); called by muse, varscan2
- ZFP91 | c.1263A>C p.K421N | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- ZFYVE27 | c.605G>T p.C202F | Missense Mutation (SNP) | VAF 154/598 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- ZNF471 | c.1469A>C p.K490T | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ZNF615 | c.1170T>G p.H390Q | Missense Mutation (SNP) | VAF 48/175 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF679 | c.256C>G p.H86D | Missense Mutation (SNP) | VAF 94/266 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- ZNF697 | c.1417C>G p.R473G | Missense Mutation (SNP) | VAF 92/342 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF705A | c.319G>T p.E107* | Nonsense Mutation (SNP) | VAF 39/186 reads (21%) | called by muse, mutect2, varscan2
- ZNF865 | c.268_288del p.E90_S96del | In Frame Del (DEL) | VAF 32/290 reads (11%) | called by mutect2, pindel
- ADAMTS20 | c.5583C>A p.S1861= | Silent (SNP) | VAF 56/140 reads (40%) | called by muse, mutect2, varscan2
- ADCYAP1R1 | c.105G>T p.L35= | Silent (SNP) | VAF 79/340 reads (23%) | catalogued as COSV100417064; called by muse, mutect2, varscan2
- AK9 | c.2271T>A p.S757= | Silent (SNP) | VAF 59/184 reads (32%) | called by muse, mutect2, varscan2
- ANKRD34C | c.1257T>C p.S419= | Silent (SNP) | VAF 88/306 reads (29%) | called by muse, mutect2, varscan2
- APC | c.7896A>T p.S2632= | Silent (SNP) | VAF 40/125 reads (32%) | called by muse, mutect2, varscan2
- ATXN7L2 | c.210G>T p.G70= | Silent (SNP) | VAF 52/152 reads (34%) | called by muse, mutect2, varscan2
- B3GNTL1 | c.486G>T p.P162= | Silent (SNP) | VAF 56/91 reads (62%) | called by muse, mutect2, varscan2
- C12orf57 | c.261C>G p.S87= | Silent (SNP) | VAF 129/819 reads (16%) | catalogued as rs1218196491, COSV57547352; called by muse, mutect2, varscan2
- C16orf72 | c.621G>T p.S207= | Silent (SNP) | VAF 69/152 reads (45%) | catalogued as COSV100588979; called by muse, mutect2, varscan2
- CACNA1I | c.4110G>C p.L1370= | Silent (SNP) | VAF 67/245 reads (27%) | called by muse, mutect2, varscan2
- CCDC82 | c.480C>T p.L160= | Silent (SNP) | VAF 66/266 reads (25%) | called by muse, varscan2
- CDC42BPB | c.735G>A p.P245= | Silent (SNP) | VAF 138/491 reads (28%) | catalogued as rs373702358; called by muse, mutect2, varscan2
- CDC42BPG | c.2385G>A p.R795= | Silent (SNP) | VAF 100/409 reads (24%) | catalogued as rs1257288623, COSV61346656; called by muse, mutect2, varscan2
- CDH7 | c.2196A>G p.T732= | Silent (SNP) | VAF 79/324 reads (24%) | catalogued as rs1232316407; called by muse, mutect2, varscan2
- DLEC1 | c.3711G>A p.A1237= | Silent (SNP) | VAF 36/313 reads (12%) | catalogued as rs377488944; called by muse, mutect2, varscan2
- DLL4 | c.616T>C p.L206= | Silent (SNP) | VAF 132/393 reads (34%) | called by muse, mutect2, varscan2
- DSP | c.603G>A p.E201= | Silent (SNP) | VAF 376/1027 reads (37%) | catalogued as rs770080985, COSV65794363; ClinVar: likely benign; called by muse, mutect2, varscan2
- EGFL8 | c.324C>G p.L108= | Silent (SNP) | VAF 29/88 reads (33%) | called by muse, mutect2, varscan2
- EYS | c.2067C>A p.P689= | Silent (SNP) | VAF 80/348 reads (23%) | called by muse, mutect2, varscan2
- FAM135B | c.804G>A p.E268= | Silent (SNP) | VAF 41/148 reads (28%) | called by muse, mutect2, varscan2
- FOXK1 | c.1227C>T p.F409= | Silent (SNP) | VAF 42/126 reads (33%) | catalogued as rs775092585; called by muse, mutect2, varscan2
- GPI | c.828G>A p.L276= | Silent (SNP) | VAF 161/649 reads (25%) | called by muse, mutect2, varscan2
- GRM8 | c.2274C>G p.L758= | Silent (SNP) | VAF 38/161 reads (24%) | catalogued as COSV58812392; called by muse, mutect2, varscan2
- HMCN1 | c.10920A>G p.T3640= | Silent (SNP) | VAF 200/463 reads (43%) | called by muse, mutect2, varscan2
- HOXD10 | c.195A>G p.Q65= | Silent (SNP) | VAF 176/418 reads (42%) | called by muse, mutect2, varscan2
- HRH2 | c.792C>A p.A264= | Silent (SNP) | VAF 130/521 reads (25%) | called by muse, mutect2, varscan2
- HTR1A | c.150G>A p.A50= | Silent (SNP) | VAF 139/371 reads (37%) | called by muse, mutect2, varscan2
- JMJD6 | c.579C>T p.T193= | Silent (SNP) | VAF 59/416 reads (14%) | called by muse, mutect2, varscan2
- KRTAP4-11 | c.438C>T p.R146= | Silent (SNP) | VAF 110/1123 reads (10%) | called by muse, mutect2
- KRTAP4-8 | c.408C>T p.R136= | Silent (SNP) | VAF 136/434 reads (31%) | called by muse, varscan2
- LRRC7 | c.4218C>G p.T1406= (on ENST00000651989 / NM_001370785.2; = p.T1326= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 31/100 reads (31%) | called by muse, mutect2, varscan2
- LYPLA1 | c.39C>A p.I13= | Silent (SNP) | VAF 37/171 reads (22%) | called by muse, mutect2, varscan2
- METTL15 | c.876G>T p.V292= | Silent (SNP) | VAF 47/234 reads (20%) | called by muse, mutect2, varscan2
- NINL | c.4146G>T p.V1382= | Silent (SNP) | VAF 40/107 reads (37%) | called by muse, mutect2, varscan2
- OR4C11 | c.162A>G p.G54= | Silent (SNP) | VAF 34/166 reads (20%) | catalogued as rs1565064685; called by muse, mutect2, varscan2
- OR51A4 | c.618C>T p.L206= | Silent (SNP) | VAF 78/213 reads (37%) | catalogued as COSV100985370; called by muse, mutect2, varscan2
- OR6N2 | c.669G>T p.G223= | Silent (SNP) | VAF 28/144 reads (19%) | catalogued as rs771360819, COSV100210082; called by muse, mutect2, varscan2
- PCDH11X | c.1539C>T p.F513= | Silent (SNP) | VAF 104/229 reads (45%) | catalogued as COSV53496834; called by muse, mutect2, varscan2
- PCDHGA11 | c.24G>T p.G8= | Silent (SNP) | VAF 62/203 reads (31%) | called by muse, mutect2, varscan2
- PLCH1 | c.3813G>T p.T1271= (on ENST00000340059 / NM_001130960.2; = p.T1263= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 190/547 reads (35%) | catalogued as COSV58190024; called by muse, mutect2, varscan2
- PPFIA2 | c.276G>T p.L92= | Silent (SNP) | VAF 12/60 reads (20%) | called by muse, mutect2, varscan2
- PREP | c.1476C>G p.L492= (on ENST00000369110; = p.L558= on NM_002726.5) | Silent (SNP) | VAF 38/132 reads (29%) | called by mutect2, varscan2
- RIN3 | c.969A>T p.T323= | Silent (SNP) | VAF 19/84 reads (23%) | called by muse, mutect2, varscan2
- RNASEH2A | c.99C>G p.V33= | Silent (SNP) | VAF 87/353 reads (25%) | called by muse, mutect2, varscan2
- RNF123 | c.2088G>T p.R696= | Silent (SNP) | VAF 151/420 reads (36%) | called by muse, mutect2, varscan2
- ROPN1L | c.540A>G p.S180= | Silent (SNP) | VAF 38/362 reads (10%) | called by muse, mutect2, varscan2
- RP1 | c.372G>T p.P124= | Silent (SNP) | VAF 79/281 reads (28%) | catalogued as COSV55114876, COSV55114898; called by muse, mutect2, varscan2
- SACS | c.975A>G p.G325= | Silent (SNP) | VAF 122/334 reads (37%) | catalogued as rs1190858438; called by muse, mutect2, varscan2
- SDK1 | c.2619G>A p.P873= | Silent (SNP) | VAF 62/224 reads (28%) | catalogued as rs146784103; called by muse, mutect2, varscan2
- SHANK3 | c.2232C>T p.P744= | Silent (SNP) | VAF 137/249 reads (55%) | catalogued as rs200258618; called by muse, mutect2, varscan2
- SLC26A3 | c.1017C>T p.T339= | Silent (SNP) | VAF 69/311 reads (22%) | catalogued as rs376695368; called by muse, mutect2, varscan2
- SLC2A2 | c.951C>T p.S317= | Silent (SNP) | VAF 78/774 reads (10%) | catalogued as rs1168244945, COSV58585880; called by muse, mutect2, varscan2
- SLC6A4 | c.1140C>T p.F380= | Silent (SNP) | VAF 23/374 reads (6%) | called by muse, mutect2
- SPTA1 | c.6039G>C p.L2013= | Silent (SNP) | VAF 259/624 reads (42%) | called by muse, mutect2, varscan2
- SRCAP | c.6111C>A p.L2037= | Silent (SNP) | VAF 81/398 reads (20%) | called by muse, mutect2, varscan2
- TMEM175 | c.1437C>T p.L479= | Silent (SNP) | VAF 123/331 reads (37%) | catalogued as rs752495871; called by muse, mutect2, varscan2
- TNXB | c.8559C>A p.G2853= (on ENST00000647633; = p.G2606= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 38/136 reads (28%) | called by muse, mutect2, varscan2
- UNC13D | c.3126G>A p.L1042= | Silent (SNP) | VAF 184/319 reads (58%) | called by muse, mutect2, varscan2
- UNC80 | c.7215G>A p.A2405= | Silent (SNP) | VAF 65/208 reads (31%) | catalogued as rs371393316; called by muse, mutect2, varscan2
- WDR26 | c.363G>T p.G121= (on ENST00000414423 / NM_001379403.1; = p.G21= on NM_025160.7) | Silent (SNP) | VAF 17/70 reads (24%) | catalogued as rs564951071; called by muse, mutect2
- WDR64 | c.3240C>A p.P1080= | Silent (SNP) | VAF 39/89 reads (44%) | catalogued as rs1558530551; called by muse, mutect2, varscan2
- WDR72 | c.1095T>C p.S365= | Silent (SNP) | VAF 68/240 reads (28%) | called by muse, mutect2, varscan2
- XIRP2 | c.9717T>C p.S3239= (on ENST00000628543; = p.S3414= on NM_152381.6) | Silent (SNP) | VAF 82/189 reads (43%) | called by muse, mutect2, varscan2
- XPO4 | c.927C>A p.I309= | Silent (SNP) | VAF 57/118 reads (48%) | called by muse, mutect2, varscan2
- ZC3H14 | c.1707G>A p.L569= | Silent (SNP) | VAF 139/552 reads (25%) | called by muse, mutect2, varscan2
- ZIC1 | c.57G>C p.A19= | Silent (SNP) | VAF 61/460 reads (13%) | catalogued as rs756393471, COSV51550355, COSV51557226; called by muse, mutect2, varscan2
- ZIC1 | c.792G>C p.P264= | Silent (SNP) | VAF 285/789 reads (36%) | catalogued as rs763617534, COSV51555265; called by muse, mutect2, varscan2
- ZNF816 | c.1455A>G p.E485= | Silent (SNP) | VAF 20/130 reads (15%) | called by muse, mutect2, varscan2
- AC073310.1 | n.689A>G | RNA (SNP) | VAF 18/103 reads (17%) | called by muse, mutect2, varscan2
- AC083899.1 | n.2991C>A | RNA (SNP) | VAF 7/29 reads (24%) | called by mutect2, varscan2
- ACO1 | c.-80G>C | 5'UTR (SNP) | VAF 63/208 reads (30%) | called by muse, mutect2, varscan2
- ACSM1 | c.1197+210C>T | Intron (SNP) | VAF 195/447 reads (44%) | catalogued as COSV99533655; called by muse, mutect2, varscan2
- AICDA | c.*15A>C | 3'UTR (SNP) | VAF 47/445 reads (11%) | called by muse, mutect2, varscan2
- ARMCX4 | c.1039-3034G>C | Intron (SNP) | VAF 29/66 reads (44%) | called by muse, mutect2, varscan2
- ATP5PB | c.-28A>G | 5'UTR (SNP) | VAF 29/126 reads (23%) | called by muse, mutect2
- B4GALNT1 | c.*1772_*1774del | 3'UTR (DEL) | VAF 61/437 reads (14%) | called by mutect2, pindel, varscan2
- BIRC6 | c.12291+668G>T | Intron (SNP) | VAF 53/242 reads (22%) | catalogued as rs1371158805; called by muse, mutect2, varscan2
- C10orf67 | c.206+636C>G | Intron (SNP) | VAF 58/290 reads (20%) | called by muse, mutect2, varscan2
- C1orf229 | n.636del | RNA (DEL) | VAF 24/118 reads (20%) | called by mutect2, pindel, varscan2
- CACNA1G | c.*154A>G | 3'UTR (SNP) | VAF 143/674 reads (21%) | catalogued as rs1423501660; called by muse, mutect2, varscan2
- CCDC138 | c.267-5del | Intron (DEL) | VAF 23/139 reads (17%) | called by mutect2, pindel, varscan2
- CENPP | c.565-45C>G | Intron (SNP) | VAF 46/174 reads (26%) | called by muse, mutect2, varscan2
- CHN1 | c.*349G>A | 3'UTR (SNP) | VAF 78/352 reads (22%) | called by muse, mutect2, varscan2
- CNOT2 | c.48+15_48+18del | Intron (DEL) | VAF 37/110 reads (34%) | called by pindel, varscan2
- ECHDC2 | c.121+34G>C | Intron (SNP) | VAF 25/86 reads (29%) | called by muse, mutect2, varscan2
- EIF3E | c.723-40C>A | Intron (SNP) | VAF 11/98 reads (11%) | called by muse, mutect2, varscan2
- EXOC6 | c.2095+1665C>G | Intron (SNP) | VAF 29/114 reads (25%) | called by muse, mutect2, varscan2
- FAM182A | n.1039T>G | RNA (SNP) | VAF 154/864 reads (18%) | called by muse, varscan2
- FOXP4 | c.204+4368A>T | Intron (SNP) | VAF 79/255 reads (31%) | called by muse, mutect2, varscan2
- GCOM1 | c.1305-16744_1305-16742del | Intron (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel
- GPR137 | chr11:64284422 C>G | 5'Flank (SNP) | VAF 51/205 reads (25%) | called by muse, mutect2, varscan2
- GPR161 | c.-139+783G>A | Intron (SNP) | VAF 22/74 reads (30%) | catalogued as rs904696283; called by muse, mutect2, varscan2
- HPD | c.93+35C>A | Intron (SNP) | VAF 112/630 reads (18%) | called by muse, mutect2, varscan2
- IGLL5 | chr22:22899586 G>A | 3'Flank (SNP) | VAF 59/250 reads (24%) | called by muse, mutect2, varscan2
- IMPA1 | c.302+519C>T | Intron (SNP) | VAF 15/49 reads (31%) | catalogued as rs530999483; called by mutect2, varscan2
- KCNMB4 | c.465-7763C>A | Intron (SNP) | VAF 40/150 reads (27%) | called by muse, mutect2, varscan2
- KLHL24 | c.1602+10_1602+11del | Intron (DEL) | VAF 10/105 reads (10%) | called by mutect2, pindel
- LCK | c.-5-110T>A | Intron (SNP) | VAF 33/151 reads (22%) | called by muse, mutect2
- LINC02740 | n.224A>C | RNA (SNP) | VAF 38/161 reads (24%) | called by muse, mutect2, varscan2
- LINC02740 | n.69G>A | RNA (SNP) | VAF 34/149 reads (23%) | catalogued as rs114287102; called by muse, mutect2, varscan2
- LIPT2 | chr11:74497443 G>T | 5'Flank (SNP) | VAF 45/149 reads (30%) | called by muse, mutect2, varscan2
- MAGEA5 | n.98C>G | RNA (SNP) | VAF 74/111 reads (67%) | called by muse, mutect2, varscan2
- MECOM | c.37+97350C>T | Intron (SNP) | VAF 23/254 reads (9%) | called by muse, mutect2
- METTL14 | c.66+1014C>T | Intron (SNP) | VAF 26/68 reads (38%) | catalogued as rs1204333643; called by muse, mutect2, varscan2
- MIR337 | n.17G>T | RNA (SNP) | VAF 26/181 reads (14%) | called by muse, mutect2, varscan2
- MPDZ | c.3255-2629A>T | Intron (SNP) | VAF 18/64 reads (28%) | called by muse, mutect2, varscan2
- MYL6 | c.428-55C>G | Intron (SNP) | VAF 206/512 reads (40%) | called by muse, mutect2, varscan2
- NBPF25P | n.878G>T | RNA (SNP) | VAF 221/1191 reads (19%) | called by muse, mutect2, varscan2
- NEDD4L | c.49-16267_49-16265del | Intron (DEL) | VAF 31/112 reads (28%) | called by mutect2, pindel, varscan2
- NLRP9 | c.2843+293G>A | Intron (SNP) | VAF 48/231 reads (21%) | called by muse, mutect2, varscan2
- NR2C1 | c.1393+723A>G | Intron (SNP) | VAF 45/139 reads (32%) | called by muse, mutect2, varscan2
- PPEF2 | c.1757-148C>G | Intron (SNP) | VAF 23/79 reads (29%) | called by muse, mutect2, varscan2
- PRAME | c.22-1830G>T | Intron (SNP) | VAF 86/294 reads (29%) | called by muse, mutect2, varscan2
- RPS3 | c.256-9C>T | Intron (SNP) | VAF 34/122 reads (28%) | called by muse, mutect2, varscan2
- RPS4X | c.361-436G>T | Intron (SNP) | VAF 41/84 reads (49%) | catalogued as COSV100289004; called by muse, mutect2, varscan2
- SAMD3 | c.654+772G>C | Intron (SNP) | VAF 49/197 reads (25%) | called by mutect2, varscan2
- SERPINA6 | c.*27C>T | 3'UTR (SNP) | VAF 100/424 reads (24%) | called by muse, mutect2, varscan2
- SLC6A10P | n.3114C>A | RNA (SNP) | VAF 139/382 reads (36%) | called by muse, mutect2, varscan2
- SNORD115-12 | n.31G>T | RNA (SNP) | VAF 183/580 reads (32%) | called by muse, mutect2, varscan2
- TNFRSF19 | c.180+821G>T | Intron (SNP) | VAF 97/260 reads (37%) | called by muse, mutect2, varscan2
- TWF1 | c.25+87G>T | Intron (SNP) | VAF 333/823 reads (40%) | catalogued as rs868670998; called by muse, mutect2, varscan2
- VAMP8 | c.162+670C>G | Intron (SNP) | VAF 43/202 reads (21%) | called by muse, mutect2, varscan2
- VPS29 | c.3+79G>A | Intron (SNP) | VAF 115/439 reads (26%) | called by muse, mutect2, varscan2
- ZNF606 | chr19:58004415 A>C | 5'Flank (SNP) | VAF 25/113 reads (22%) | called by muse, mutect2, varscan2
